CGCI case HTMCP-03-06-02399 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ecaf3572-236e-413d-8fed-1bf5dbb99364

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 42 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 42.0 years (15,345 days); Year of diagnosis: 2016; Method of diagnosis: Biopsy; AJCC clinical T: T1b2; AJCC clinical N: NX; AJCC clinical M: MX; FIGO stage: Stage IB2; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 398 days (1.1 years).
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Paclitaxel; Initial disease status: Initial Diagnosis; Days to treatment start: 20 days; Days to treatment end: 163 days; Number of cycles: 6.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Partial Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 398 days (1.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day 0: Weight: 45.1 kg; Height: 160.5 cm; BMI: 17.5; Hormonal contraceptive use: Former User; Hysterectomy type: Not Performed; Menopause status: Premenopausal; Pregnant at diagnosis: No.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02399-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02399-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02399-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Weight kg at diagnosis: 45.1 kg; History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 02; Pregnancies count miscarriage: 00; Pregnancies count induced abortion: 00; Pregnancies count ectopic: 00; Pregnancies count stillbirth: 00; Total pregnancy count: 02; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Keratinizing; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: HIV status: Negative.
- Follow-up form: Tumor status: With tumor; Treatment outcome first course: Partial Remission/Response.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Paclitaxel + Cisplatin; Pharma adjuvant cycles count: 6.

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet02_20191105.xlsx (sheet validation DNAs), for sample HTMCP-03-06-02399-01A-01D-10409:
- % tumour top: 70
- % tumour bottom: 60

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet02_20191105.xlsx (sheet validation DNAs), for sample HTMCP-03-06-02399-10A-01D-10409:
- % tumour top: 0
- % tumour bottom: 0

Additional fields from the CGCI biospecimen supplement workbook CGCI-HTMCP-CC_biospecimenSupplementSpreadsheet_20191105.xlsx, for sample HTMCP-03-06-02399-01A-02D-10409:
- % tumour top: 70
- % tumour bottom: 60
